Somatic mutation profile of tumor specimen MBCProject_6109_T1A_WES (aliquot MBCProject_6109_T1A_WES_1) from CMI case MBCProject_6109, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.0 years (11,672 days).
Specimen MBCProject_6109_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb32a4f9-5a7b-4dd8-a969-f4d9ddd40c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6109_SALIVA_2 (Saliva), aliquot MBCProject_6109_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/148f8981-f94a-4cb3-a4ed-b98afd285b44

The open-access MAF lists 108 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 22, Nonsense Mutation 6, Intron 6, Splice Region 2, RNA 2, 3'UTR 2, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54097958, COSV99698377, COSV99699552; called by muse, mutect2
- ARAP2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV58292911; called by muse, mutect2, varscan2
- BARD1 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs876658147, COSV99639650; ClinVar: uncertain significance; called by muse, mutect2
- BTN3A3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs574858167, COSV55071633; called by mutect2, varscan2
- DNAH5 | c.7943C>T p.A2648V | Missense Mutation (SNP) | VAF 56/476 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs201939338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57253359; called by muse, varscan2
- FANCA | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 39/502 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV66882606; called by muse, mutect2
- FGD1 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.012); catalogued as COSV100910847; called by muse, mutect2, varscan2
- GATA3 | c.1003dup p.D335Gfs*17 | Frame Shift Ins (INS) | VAF 165/840 reads (20%) | catalogued as COSV60519609; called by mutect2, pindel, varscan2
- GMPS | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99903466; called by muse, mutect2, varscan2
- INVS | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 86/594 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs761806481, COSV99318409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 87/467 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs370557951, COSV100069359; called by muse, mutect2, varscan2
- KHDRBS1 | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.765); catalogued as rs1164069438; called by muse, mutect2, varscan2
- KIDINS220 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs775892620, COSV56750260; called by muse, mutect2, varscan2
- LHFPL3 | c.402C>T p.S134= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as rs565371746; called by mutect2, varscan2
- MUC16 | c.13567G>T p.A4523S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV67494623; called by muse, mutect2
- P3H1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1163925418; called by muse, mutect2, varscan2
- PACS1 | c.203C>G p.S68W | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.377); catalogued as COSV57699369; called by muse, mutect2
- PDE4D | c.1910G>A p.R637Q (on ENST00000340635 / NM_001104631.2; = p.R501Q on NM_006203.4) | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as rs369556531; called by muse, mutect2
- RANBP2 | c.4672G>A p.A1558T | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs1440492329; called by muse, mutect2, varscan2
- SEMA6B | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs755696579, COSV56704146; called by muse, mutect2
- SPDYE4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1463425414, COSV104409726; called by muse, mutect2, varscan2
- STOML3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 143/522 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1318298606, COSV65511162; called by muse, mutect2, varscan2
- SVIL | c.5489C>T p.A1830V (on ENST00000355867 / NM_021738.3; = p.A1404V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/620 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs955294945, COSV63439412; called by muse, mutect2, varscan2
- TDRKH | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757835193, COSV100918077, COSV64316350; called by muse, mutect2
- THAP3 | c.607C>T p.R203W (on ENST00000054650 / NM_001195753.1; = p.R202W on NM_001195752.1) | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs545814166; called by muse, mutect2, varscan2
- TRIM32 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1211253312; called by muse, mutect2
- UBR5 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780579895, COSV55283970, COSV55302532; called by muse, mutect2, varscan2
- ZNF461 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV100831517; called by muse, mutect2
- ZNF579 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1236250229; called by muse, mutect2, varscan2
- ABHD16A | c.447C>G p.Y149* | Nonsense Mutation (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- APC | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- AREL1 | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.3435G>C p.Q1145H | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATAD2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, varscan2
- C12orf29 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 26/380 reads (7%) | called by muse, mutect2
- CCDC9B | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- COG2 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 55/467 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CUX2 | c.2544G>T p.R848S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYFIP2 | c.1932G>T p.Q644H (on ENST00000616178 / NM_001291722.2; = p.Q619H on NM_014376.4) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CYP2W1 | c.1285+3C>T | Splice Region (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- DGKD | c.1323G>C p.K441N (on ENST00000264057 / NM_152879.3; = p.K397N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DOCK2 | c.5456G>C p.G1819A | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2
- DSG4 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUSP6 | c.1028T>A p.F343Y | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EHMT1 | c.3751G>A p.G1251S | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FBRSL1 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- FGFR1 | c.1505A>C p.K502T (on ENST00000447712 / NM_023110.3; = p.K500T on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2
- FSD1 | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GALNT7 | c.1748A>G p.D583G | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GAS2L1 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HEATR1 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- KANSL3 | c.1922C>G p.S641C (on ENST00000666923 / NM_001349262.2; = p.S615C on NM_001115016.3) | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- LRIG1 | c.573_584del p.T192_L195del | In Frame Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- LYVE1 | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- METTL25 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- MTUS1 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- MYLIP | c.12T>G p.Y4* | Nonsense Mutation (SNP) | VAF 23/266 reads (9%) | called by muse, mutect2
- NOL4L | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.138); called by muse, mutect2
- PDCD1 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.346); called by muse, mutect2
- PRPF38B | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2
- PSME1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.28); called by muse, mutect2
- RALGAPB | c.4051T>C p.Y1351H | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SCCPDH | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPING1 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLC26A7 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35F3 | c.142G>A p.G48S (on ENST00000366617 / NM_001300845.1; = p.G117S on NM_173508.4) | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); called by mutect2, varscan2
- SMARCA1 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SOCS4 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- SOGA3 | c.2670C>A p.D890E | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.086); called by muse, mutect2
- SOX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 40/662 reads (6%) | called by muse, mutect2
- SPTA1 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 99/819 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TRMT1L | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 42/663 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WDR11 | c.876A>T p.L292F | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2
- YEATS2 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- APEX2 | c.828T>A p.L276= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ATG2B | c.5724C>T p.V1908= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.213G>A p.Q71= | Silent (SNP) | VAF 30/272 reads (11%) | called by muse, mutect2, varscan2
- CKAP4 | c.1416G>A p.V472= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- CLUL1 | c.708G>A p.P236= | Silent (SNP) | VAF 50/233 reads (21%) | catalogued as rs548196095; called by muse, mutect2, varscan2
- DISP2 | c.2553C>T p.A851= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- DOCK2 | c.5457C>T p.G1819= | Silent (SNP) | VAF 24/300 reads (8%) | catalogued as rs560711325; called by muse, mutect2
- FBLN2 | c.498T>A p.G166= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- GPR162 | c.258C>T p.N86= | Silent (SNP) | VAF 13/279 reads (5%) | catalogued as rs1377735189, COSV50592391; called by muse, mutect2
- HYDIN | c.5733G>A p.K1911= | Silent (SNP) | VAF 24/176 reads (14%) | called by mutect2, varscan2
- IL1RAP | c.240G>A p.E80= | Silent (SNP) | VAF 91/765 reads (12%) | called by muse, mutect2, varscan2
- KIAA1841 | c.1461G>A p.L487= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as rs1434536955, COSV54379718; called by muse, mutect2
- KPRP | c.1332G>A p.P444= | Silent (SNP) | VAF 17/299 reads (6%) | catalogued as COSV64222659, COSV64222700; called by muse, mutect2
- NOL6 | c.3279G>T p.P1093= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV99954698; called by muse, mutect2
- NTN5 | c.1179C>T p.A393= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs1310298271; called by muse, mutect2, varscan2
- PCNX1 | c.6687C>G p.T2229= | Silent (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- PEX11A | c.657T>A p.P219= | Silent (SNP) | VAF 44/356 reads (12%) | called by muse, mutect2, varscan2
- PHF8 | c.2310A>G p.S770= (on ENST00000357988 / NM_001184896.1; = p.S734= on NM_015107.3) | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- SLC12A6 | c.3369G>A p.E1123= (on ENST00000354181 / NM_001365088.1; = p.E1072= on NM_005135.2) | Silent (SNP) | VAF 53/470 reads (11%) | called by muse, mutect2, varscan2
- SORCS3 | c.255C>T p.A85= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- TRAK1 | c.2112G>A p.L704= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs528706359; called by muse, mutect2, varscan2
- USP54 | c.1035G>A p.L345= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs778936680; called by muse, mutect2
- ADD2 | c.1593+28G>A | Intron (SNP) | VAF 6/114 reads (5%) | catalogued as rs782028665, COSV100036471, COSV52454503; called by muse, mutect2
- CBFA2T3 | c.151+25430C>T | Intron (SNP) | VAF 52/330 reads (16%) | catalogued as rs879110606; called by muse, mutect2, varscan2
- CLCN7 | c.1617+28G>C | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- CLK2P1 | n.718C>T | RNA (SNP) | VAF 31/650 reads (5%) | called by muse, mutect2
- DMGDH | c.2250+2593C>A | Intron (SNP) | VAF 33/417 reads (8%) | called by muse, mutect2
- HOXD1 | c.-88G>A | 5'UTR (SNP) | VAF 12/105 reads (11%) | catalogued as rs759685438; called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1494G>C | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- MED12 | c.2542-10C>A | Intron (SNP) | VAF 48/290 reads (17%) | called by muse, mutect2, varscan2
- MUC19 | n.5000G>C | RNA (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- RAB18 | c.*3986G>A | 3'UTR (SNP) | VAF 51/789 reads (6%) | called by muse, mutect2
- SNTB1 | c.*158C>T | 3'UTR (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
